CCDI case PBBVUP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1222a342-119f-4f9f-b162-cfbe75883f1c

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Biospecimens (3 samples)
- Sample 0DIMVW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWR: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMWU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
